Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A6BQ, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A6BQ-01A (Primary Tumor).

[page 1 of 2]
THIS IS A CONFIDENTIAL AND PRIVILEGED COMMUNICATION
PLEASE DISPOSE OF PAPER COPIES APPROPRIATELY

Printed by:

Name: [REDACTED]
Test Name: F/S PLEURA{PLEURA
Ordered By:

Age:
Test Date:

COLLECTION DATE:
SPECIMEN NUMBER: [REDACTED]

SPECIMENS:
1. F/S PLEURA
2. PLEURA

ICD-O-3 NOS
Mesothelioma, epithelial
9052/3
Site Pleura NOS C38.4
JW 5/16/13

DIAGNOSIS:

1. PLEURA, BIOPSY:
- MALIGNANT MESOTHELIOMA, EPITHELIAL TYPE (SEE COMMENT)
- NON-NECROTIZING GRANULOMATOUS INFLAMMATION
2. PLEURA, BIOPSY:
- MALIGNANT MESOTHELIOMA, EPITHELIAL TYPE (SEE COMMENT)
- NON-NECROTIZING GRANULOMATOUS INFLAMMATION

Comment: The immunostains show the tumor cells to be diffusely positive for calretinin, WT-1 and CK5/6 and focally positive for D2-40, supporting the diagnosis. The AFB and GMS are negative for microorganisms.

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:
Pleural tumor

MACROSCOPIC DESCRIPTION:
The specimen is received in two parts each labeled with the patient's name.

1. Part one is received fresh labeled 'pleura for frozen section'. It consists of four fragments of pink-yellow fibrofatty tissue measuring 0.5 x 0.6 x 0.4 cm, 1.2 x 0.8 x 0.3 cm, 0.9 x 0.9 x 0.4 cm, and 1 x 0.7 x 0.3 cm. Representative fragments are submitted for tissue banking. A representative section is submitted for frozen section diagnosis. The remainder is submitted in entirety.
2. Part two is received in saline labeled 'pleura' and consists of multiple pieces of pink-yellow rubbery tissue measuring 2 x 1 x 0.3 cm in aggregate. The specimen is submitted in entirety.

[page 2 of 2]
SUMMARY OF SECTIONS:

1A representative for frozen section diagnosis

1B remainder of specimen

2A in toto

SPECIAL PROCEDURES:

Calretinin, CK 5/6, WT1, D2-40

GMS, AFB

INTRA - OPERATIVE CONSULTATION:

1. Pleura, biopsy:

- Epithelioid tumor favor mesothelioma

Results reported by Dr. _____ to Dr. _____ in person at _____

Intra-Operative Consultation #1 performed by _____

Electronically signed _____

Final Diagnosis performed by _____

Electronically signed _____

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by _____

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 425acf7e-522a-495d-b69f-b59135555826 (TCGA-MQ-A6BQ.476705A9-0D92-4852-8204-8CA7807688B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).